Somatic mutation profile of tumor specimen TCGA-EK-A2RA-01A (aliquot TCGA-EK-A2RA-01A-11D-A18J-09) from TCGA case TCGA-EK-A2RA, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA2; Tumor grade: G3; Age at diagnosis: 74.5 years (27,209 days).
Specimen TCGA-EK-A2RA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e05ec1e4-77bb-41a0-ae0c-37ec78aeb7d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EK-A2RA-10A (Blood Derived Normal), aliquot TCGA-EK-A2RA-10A-01D-A18J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e69b50b-7a24-4e47-9c2c-52e51c33e403

The open-access MAF lists 245 somatic variants for this specimen: 172 protein-altering or splice-affecting, 65 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 149, Silent 65, Nonsense Mutation 13, Splice Site 3, RNA 3, 5'Flank 3, Frame Shift Del 2, Intron 2, Frame Shift Ins 2, In Frame Del 1, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAPK1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 17/45 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519911, COSV53184855, COSV99308005; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.3145C>T p.Q1049* (on ENST00000272895 / NM_173076.3; = p.Q731* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV55958093; called by muse, mutect2, varscan2
- ABCA4 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.736); catalogued as rs754899561, CM070626, COSV64673307; called by muse, mutect2, varscan2
- ABI3BP | c.135G>C p.L45F | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.738); catalogued as COSV52535298; called by muse, mutect2, varscan2
- ACD | c.874C>T p.H292Y (on ENST00000620338; = p.H203Y on NM_022914.3) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV54667465; called by muse, mutect2, varscan2
- ADD1 | c.1191C>A p.Y397* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as COSV53268831; called by muse, mutect2
- ADD3 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.102); catalogued as COSV99523808; called by muse, mutect2
- AHRR | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1243610648, COSV100328030; called by muse, mutect2
- AKAP8 | c.1581G>C p.L527F | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV54102358; called by muse, mutect2, varscan2
- AKR1A1 | c.147C>G p.I49M | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV61086776; called by muse, mutect2, varscan2
- ALAD | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52958806; called by muse, mutect2, varscan2
- ALDH4A1 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 11/88 reads (13%) | catalogued as rs756807746, COSV51892302; called by muse, mutect2, varscan2
- ALPP | c.530C>T p.S177L | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371726976, COSV101235044; called by muse, mutect2, varscan2
- ANKRD42 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.67); PolyPhen benign (0.02); catalogued as COSV52615665; called by muse, mutect2, varscan2
- AP1B1 | c.198G>T p.K66N | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58017265; called by muse, mutect2, varscan2
- APBA3 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV100349517, COSV57462621; called by muse, mutect2, varscan2
- APC2 | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as COSV52018175; called by muse, mutect2, varscan2
- ARAP1 | c.1829A>G p.N610S (on ENST00000393609 / NM_001040118.2; = p.N365S on NM_015242.4) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV61990930; called by muse, mutect2
- ARF6 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV100028491, COSV53597553; called by muse, mutect2, varscan2
- ATN1 | c.2560C>G p.L854V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.285); catalogued as COSV63110961; called by muse, mutect2, varscan2
- ATP2B2 | c.1389G>A p.M463I (on ENST00000352432; = p.M429I on NM_001683.5) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV59495773; called by muse, mutect2, varscan2
- BAG6 | c.3430C>T p.R1144W (on ENST00000676571; = p.R1097W on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs745856906, COSV52990323; called by muse, mutect2, varscan2
- BIRC6 | c.11600C>T p.S3867L | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs1377701957, COSV70198850; called by muse, mutect2, varscan2
- BOC | c.1204G>T p.A402S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.349); catalogued as COSV56350400; called by muse, mutect2
- BOD1L1 | c.2044C>T p.R682C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as rs768340636, COSV50012031; called by muse, mutect2, varscan2
- C14orf28 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.009); catalogued as COSV57333288; called by muse, mutect2, varscan2
- CALD1 | c.1209G>C p.K403N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV62647592; called by muse, varscan2
- CCR1 | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as rs201235369, COSV56122155; called by muse, mutect2, varscan2
- CCT6B | c.707C>A p.S236* | Nonsense Mutation (SNP) | VAF 3/35 reads (9%) | catalogued as COSV58489951; called by muse, mutect2
- CD14 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as rs777233725, COSV57369848; called by muse, mutect2, varscan2
- CEMIP | c.2246C>T p.S749F | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV54992170; called by muse, mutect2, varscan2
- CFAP47 | c.59G>T p.S20I | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.32); catalogued as COSV52884192; called by muse, mutect2, varscan2
- CFAP70 | c.310C>G p.L104V | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100161147; called by muse, mutect2
- CHD9 | c.5650G>C p.E1884Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as COSV54610063; called by muse, mutect2, varscan2
- CHIA | c.541A>C p.T181P (on ENST00000343320; = p.T73P on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV58475149; called by muse, mutect2
- COG4 | c.1517C>T p.P506L | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs940522796, COSV60422445; called by muse, mutect2, varscan2
- CRHR1 | c.596T>C p.F199S (on ENST00000398285 / NM_001145146.2; = p.F170S on NM_004382.5) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV53278409; called by muse, mutect2, varscan2
- CSTF1 | c.878C>G p.S293* | Nonsense Mutation (SNP) | VAF 11/104 reads (11%) | catalogued as COSV53858641; called by muse, mutect2, varscan2
- CTDP1 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377684676; called by muse, mutect2, varscan2
- CTIF | c.925G>C p.E309Q | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.036); catalogued as COSV56483387; called by muse, mutect2, varscan2
- CTNNA1 | c.1939G>C p.D647H | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV57073527; called by muse, mutect2, varscan2
- CYP2A6 | c.674C>T p.S225L | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.572); catalogued as rs1465959396, COSV99991835; called by muse, mutect2, varscan2
- DCAF4L2 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV60478406; called by muse, mutect2, varscan2
- DCUN1D3 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as COSV60953217; called by muse, mutect2, varscan2
- DDX46 | c.2539G>A p.E847K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.05); catalogued as COSV62799213; called by muse, mutect2, varscan2
- DENND6A | c.1407G>T p.K469N | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100231675; called by muse, mutect2, varscan2
- DMD | c.2017C>G p.Q673E | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.096); catalogued as rs128626232, CM950339, COSV55868752; called by muse, mutect2, varscan2
- DMTN | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1373752281, COSV56112546; called by muse, mutect2, varscan2
- DRP2 | c.1345C>T p.H449Y | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV65810244; called by muse, mutect2, varscan2
- DSCAML1 | c.388G>A p.V130M (on ENST00000321322; = p.V70M on NM_020693.4) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1393957887, COSV58382031; called by muse, mutect2, varscan2
- DSE | c.694T>C p.W232R | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1217613362, COSV59063721; called by muse, mutect2, varscan2
- DST | c.21878G>A p.R7293Q (on ENST00000361203 / NM_001374722.1; = p.R4966Q on NM_015548.5) | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs767051612, COSV55004480; called by muse, mutect2, varscan2
- DYRK1A | c.1906C>T p.P636S | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.968); catalogued as COSV100118387; called by muse, mutect2
- ESCO1 | c.1688C>G p.S563C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV52519585; called by muse, mutect2, varscan2
- FAM135B | c.3944A>G p.Q1315R | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52722653; called by muse, mutect2
- FATE1 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as rs771974546, COSV64848962; called by muse, mutect2, varscan2
- FBXO41 | c.1759G>A p.A587T | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs772369672, COSV54584193; called by muse, mutect2, varscan2
- FIBP | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1305967737, COSV57033693; called by muse, mutect2, varscan2
- FLG | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV64239455, COSV64241431; called by muse, mutect2, varscan2
- FOXA3 | c.143C>G p.S48C | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV56215902; called by muse, mutect2, varscan2
- GAGE12H | c.105A>C p.E35D | Missense Mutation (SNP) | VAF 100/502 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV67752867; called by muse, mutect2, varscan2
- GAR1 | c.268A>G p.T90A | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.371); catalogued as COSV56993271; called by muse, mutect2, varscan2
- GFPT2 | c.795C>T p.S265= | Splice Region (SNP) | VAF 6/21 reads (29%) | catalogued as rs749759408, COSV53808304; called by muse, mutect2
- GJB6 | c.291C>G p.Y97* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | catalogued as COSV53832523; called by muse, varscan2
- GPRC5B | c.622A>C p.M208L | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.881); catalogued as COSV56026351; called by muse, mutect2, varscan2
- GRIA2 | c.1049A>T p.Q350L | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.435); catalogued as COSV52389260; called by muse, mutect2, varscan2
- GRIN2B | c.3316G>A p.E1106K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs199799650, COSV74204786, COSV74206480; called by muse, mutect2
- GRM5 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.253); catalogued as COSV59603646; called by muse, mutect2, varscan2
- GTF3C1 | c.6298G>A p.E2100K | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs759721942, COSV62238718; called by muse, mutect2, varscan2
- GTF3C1 | c.1584G>C p.L528F | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.178); catalogued as COSV62241004; called by muse, mutect2, varscan2
- HPR | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs761265530, COSV57182441; called by muse, mutect2, varscan2
- HSP90AA1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV53488534; called by muse, mutect2, varscan2
- ICE1 | c.3781G>C p.E1261Q | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as COSV56823849; called by muse, mutect2, varscan2
- IGLV2-8 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs750475072; called by muse, mutect2, varscan2
- IL23R | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV61374225; called by muse, mutect2, varscan2
- IQGAP3 | c.3259G>C p.E1087Q | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63251181; called by muse, mutect2, varscan2
- KCNN3 | c.1774C>T p.R592W (on ENST00000618040 / NM_001204087.1; = p.R577W on NM_002249.6) | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55216437; called by muse, mutect2, varscan2
- KDM3A | c.2645C>G p.S882C | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV57220800; called by muse, mutect2, varscan2
- KDM7A | c.1369G>C p.D457H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV50090155; called by muse, mutect2, varscan2
- LDB2 | c.425G>C p.R142T | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58768656; called by muse, mutect2, varscan2
- LSP1 | c.823C>T p.Q275* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as rs1286881238, COSV61134086; called by muse, mutect2, varscan2
- LTBP2 | c.2377C>G p.Q793E | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV56207743; called by muse, mutect2, varscan2
- MAP2K1 | c.1046G>A p.R349K | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57234324; called by muse, mutect2, varscan2
- MCEMP1 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs142070554; called by muse, mutect2
- MFAP1 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.723); catalogued as COSV51038958; called by muse, mutect2, varscan2
- MICAL3 | c.3052G>T p.E1018* | Nonsense Mutation (SNP) | VAF 9/41 reads (22%) | catalogued as COSV68729935; called by muse, mutect2, varscan2
- MLEC | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.094); catalogued as COSV57329590; called by muse, mutect2, varscan2
- MMEL1 | c.1652G>A p.S551N | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as rs1557520948, COSV56521281; called by muse, mutect2, varscan2
- MUC17 | c.1910G>T p.S637I | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV100075481, COSV60301086; called by muse, mutect2, varscan2
- MYH1 | c.4690C>T p.R1564C | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs555367957, COSV56847943; called by muse, mutect2, varscan2
- MYH10 | c.5581G>A p.E1861K | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs748972290, COSV52600452; called by muse, mutect2, varscan2
- MYH11 | c.3105G>C p.M1035I | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs930631886, COSV55552137, COSV55555238; called by muse, mutect2, varscan2
- MYLK | c.2818G>C p.E940Q | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as COSV60621917; called by muse, mutect2
- NDST2 | c.2461G>C p.E821Q | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.365); catalogued as COSV55214261; called by muse, mutect2, varscan2
- NLRX1 | c.1974C>G p.I658M | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.051); catalogued as COSV52704107; called by muse, mutect2, varscan2
- OR10Q1 | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as rs1288124802, COSV57470385; called by muse, mutect2, varscan2
- OR6B3 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); catalogued as rs771193171, COSV100096880, COSV60113862; called by muse, mutect2, varscan2
- PAPPA2 | c.5063C>G p.P1688R | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV62796909; called by muse, mutect2, varscan2
- PAX8 | c.1085C>G p.S362* | Nonsense Mutation (SNP) | VAF 8/35 reads (23%) | catalogued as COSV54508305; called by muse, mutect2, varscan2
- PCDHA13 | c.1199C>G p.T400S | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.804); catalogued as COSV56498349; called by muse, mutect2, varscan2
- PCDHA3 | c.2259G>C p.Q753H | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs372857774; called by muse, mutect2, varscan2
- PER3 | c.2453G>A p.G818E | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.497); catalogued as COSV100728529; called by muse, mutect2
- POFUT1 | c.195G>C p.L65F | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55788243; called by muse, mutect2, varscan2
- PORCN | c.1093C>T p.R365W (on ENST00000326194 / NM_203475.3; = p.R354W on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs398124616, CM073268, CM1210993, COSV100400507, COSV58226160; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPP1R12A | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV54108011; called by muse, mutect2, varscan2
- PPP5C | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV50140019; called by muse, mutect2, varscan2
- PRX | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.91); catalogued as COSV52529684, COSV52531464, COSV99397832; called by muse, mutect2, varscan2
- R3HDML | c.514-1G>A p.X172_splice | Splice Site (SNP) | VAF 7/82 reads (9%) | catalogued as COSV99407322; called by muse, mutect2
- RAD54L2 | c.1483C>G p.L495V | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56578435, COSV99621747; called by muse, mutect2, varscan2
- RFX3 | c.1062G>C p.Q354H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV56514364; called by muse, mutect2, varscan2
- RGS3 | c.3285C>A p.F1095L (on ENST00000350696 / NM_001282923.2; = p.F814L on NM_130795.4) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59515881; called by muse, mutect2, varscan2
- RHBG | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.381); catalogued as rs776794312, COSV54803928; called by muse, mutect2, varscan2
- RHNO1 | c.631G>C p.V211L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV63485307; called by muse, mutect2, varscan2
- RIMS1 | c.2200G>T p.A734S | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.742); catalogued as COSV99331268; called by muse, mutect2
- RTEL1 | c.2284C>T p.R762W | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as rs750251447, COSV58890812, COSV58893591; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RUSC2 | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769971449, COSV63428536; called by muse, mutect2, varscan2
- RXRA | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62684206; called by muse, mutect2, varscan2
- RYR1 | c.7105C>T p.R2369W | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV62096336; called by muse, mutect2, varscan2
- SAMD10 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1368089363, COSV53870178; called by muse, mutect2, varscan2
- SAMD8 | c.728G>T p.R243L | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65509832; called by muse, mutect2
- SBNO1 | c.817G>A p.D273N (on ENST00000420886; = p.D272N on NM_018183.5) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as rs1566042751, COSV57341284; called by muse, mutect2, varscan2
- SCN7A | c.1963G>C p.E655Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.129); catalogued as COSV101313168, COSV69271225; called by muse, mutect2, varscan2
- SERPINB11 | c.552C>G p.F184L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV66956906, COSV66956940; called by mutect2, varscan2
- SGMS1 | c.1137G>C p.K379N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.196); catalogued as COSV62370354; called by muse, mutect2, varscan2
- SIN3A | c.730C>G p.Q244E | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV64582805, COSV64585383; called by muse, mutect2, varscan2
- SLC12A2 | c.2791C>G p.L931V | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.045); catalogued as COSV52471020; called by muse, mutect2, varscan2
- SLC16A4 | c.711C>G p.I237M | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as COSV63916493; called by muse, mutect2
- SLC38A8 | c.577G>A p.V193M | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as rs930213649, COSV55304722; called by muse, mutect2, varscan2
- SPEG | c.4711G>C p.E1571Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV56663078, COSV56668154; called by muse, mutect2, varscan2
- SPHKAP | c.4548C>A p.S1516R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV60877592; called by muse, mutect2, varscan2
- SRMS | c.70G>A p.G24S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.047); catalogued as rs543252716, COSV53920615; called by muse, mutect2
- STAT5A | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV61806663; called by muse, mutect2, varscan2
- TAF11 | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | catalogued as COSV51955211; called by muse, mutect2, varscan2
- TBC1D9 | c.3716G>A p.R1239K | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV71307417; called by muse, mutect2, varscan2
- TECTA | c.6365G>A p.R2122K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.219); catalogued as COSV50705213; called by muse, mutect2, varscan2
- TEX11 | c.2281G>A p.E761K (on ENST00000344304; = p.E746K on NM_031276.3) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV60230120; called by muse, mutect2, varscan2
- TEX15 | c.1891G>A p.E631K (on ENST00000256246; = p.E1014K on NM_001350162.2) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV56342375; called by muse, mutect2, varscan2
- TEX15 | c.1477G>C p.E493Q (on ENST00000256246; = p.E876Q on NM_001350162.2) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.415); catalogued as COSV56345868; called by muse, mutect2, varscan2
- TNFRSF8 | c.1544-1G>A p.X515_splice | Splice Site (SNP) | VAF 8/64 reads (13%) | catalogued as COSV55796284; called by muse, mutect2, varscan2
- TNIP3 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV50247577; called by muse, mutect2, varscan2
- TNK2 | c.880T>C p.F294L | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57369064; called by muse, mutect2, varscan2
- TRIM11 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.065); catalogued as COSV52857699; called by muse, mutect2, varscan2
- TRPC4AP | c.1226G>A p.R409K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs1249748759, COSV52679497; called by muse, mutect2, varscan2
- TRPC5 | c.801C>G p.I267M | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV99463172; called by muse, mutect2, varscan2
- TSEN2 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.157); catalogued as rs1217983707, COSV53188764; called by muse, mutect2, varscan2
- TSEN2 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs750726691, COSV53188786; called by muse, mutect2, varscan2
- ULBP1 | c.445C>G p.L149V | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV57664090; called by muse, mutect2, varscan2
- USP15 | c.970G>A p.E324K (on ENST00000280377 / NM_001351159.2; = p.E295K on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV54791509; called by muse, mutect2, varscan2
- USP43 | c.1069C>G p.Q357E | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.041); catalogued as COSV53301982, COSV99557086; called by muse, mutect2, varscan2
- WDR36 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.024); catalogued as rs906156994, COSV72411146; called by muse, mutect2, varscan2
- XDH | c.3242C>T p.S1081F | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65147052; called by muse, mutect2, varscan2
- XIRP1 | c.4178G>C p.G1393A | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.14); catalogued as COSV100454060, COSV61137252; called by muse, mutect2, varscan2
- ZAN | c.4134C>G p.F1378L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.068); catalogued as COSV61808662; called by muse, mutect2
- ZAN | c.4804G>A p.V1602I | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs764326853, COSV61804865; called by muse, mutect2, varscan2
- ZBTB17 | c.662-1G>A p.X221_splice | Splice Site (SNP) | VAF 8/72 reads (11%) | catalogued as COSV65269532; called by muse, mutect2, varscan2
- ZC3H15 | c.57G>C p.K19N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV61922276; called by muse, mutect2, varscan2
- ZHX3 | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV58383125; called by muse, mutect2, varscan2
- ZNF385B | c.48G>A p.M16I | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.974); catalogued as COSV69802612; called by muse, mutect2, varscan2
- ZNF501 | c.625G>C p.E209Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV68516293, COSV68516658; called by muse, mutect2, varscan2
- ZNF536 | c.1051G>A p.G351S | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62819589, COSV62820183, COSV62820593; called by muse, mutect2, varscan2
- ZNF559-ZNF177 | c.429G>A p.M143I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as rs1259711819, COSV58673421, COSV58674284; called by muse, mutect2, varscan2
- ZNF835 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs922601671, COSV73379420; called by muse, mutect2, varscan2
- ZNF99 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.436); catalogued as COSV68055654, COSV68055838; called by muse, mutect2, varscan2
- ZSCAN5A | c.1302C>A p.H434Q | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54226410; called by muse, mutect2, varscan2
- EIF4A2 | c.248_258del p.K83Ifs*12 | Frame Shift Del (DEL) | VAF 43/78 reads (55%) | called by mutect2, pindel, varscan2
- GPR179 | c.3674A>G p.E1225G (on ENST00000621958; = p.E1224G on NM_001004334.4) | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- PTCHD1 | c.2525dup p.L842Ffs*12 | Frame Shift Ins (INS) | VAF 9/55 reads (16%) | called by mutect2, pindel, varscan2
- SDHAF3 | c.-5_13del | Translation Start Site (DEL) | VAF 15/82 reads (18%) | called by mutect2, pindel, varscan2
- SLC7A14 | c.1022_1030del p.G341_V343del | In Frame Del (DEL) | VAF 18/64 reads (28%) | called by mutect2, pindel, varscan2
- SYT3 | c.1109del p.F370Sfs*81 | Frame Shift Del (DEL) | VAF 29/70 reads (41%) | called by mutect2, pindel, varscan2
- TAS2R41 | c.236dup p.L80Sfs*34 | Frame Shift Ins (INS) | VAF 9/54 reads (17%) | called by mutect2, pindel, varscan2
- TRGC1 | c.301C>G p.Q101E | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.436); called by muse, varscan2
- ACLY | c.972C>G p.L324= | Silent (SNP) | VAF 34/57 reads (60%) | catalogued as COSV61250557; called by muse, mutect2, varscan2
- ALG1L | c.291G>A p.V97= | Silent (SNP) | VAF 24/175 reads (14%) | catalogued as COSV61075935; called by muse, mutect2, varscan2
- AR | c.2694G>A p.E898= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV65956488, COSV65958458; called by muse, mutect2, varscan2
- ARHGEF40 | c.720C>T p.G240= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs756876876, COSV53880104; called by muse, mutect2, varscan2
- ATP11A | c.2301G>A p.L767= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV52111045; called by muse, mutect2, varscan2
- BARHL2 | c.123G>A p.A41= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV64980783; called by muse, mutect2, varscan2
- BDKRB1 | c.132C>T p.I44= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV53706101, COSV53706421; called by muse, mutect2, varscan2
- BRWD3 | c.1977C>T p.D659= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV64747590; called by muse, mutect2, varscan2
- COLGALT1 | c.1773C>T p.S591= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV53108765; called by muse, mutect2
- CORO7 | c.855G>C p.L285= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs959591861, COSV52029748; called by muse, mutect2, varscan2
- CYB5R1 | c.6G>A p.G2= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV65916963; called by muse, mutect2, varscan2
- CYP2A6 | c.927C>G p.T309= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as COSV56535119, COSV99992126; called by muse, mutect2, varscan2
- DAW1 | c.1059C>T p.F353= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV59365170; called by muse, mutect2, varscan2
- DENND4C | c.4719C>T p.F1573= (on ENST00000434457 / NM_001330640.2; = p.F1524= on NM_017925.7) | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV63008730; called by muse, mutect2
- DHX57 | c.3855G>A p.E1285= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV99770037; called by muse, mutect2
- ECT2L | c.663A>G p.R221= | Silent (SNP) | VAF 43/55 reads (78%) | catalogued as COSV62884319; called by muse, mutect2, varscan2
- ERBB4 | c.1431C>G p.L477= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV53603699; called by muse, mutect2, varscan2
- FCGR3B | c.15C>G p.L5= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV54212773; called by muse, mutect2, varscan2
- GPR68 | c.129C>G p.L43= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV53176296; called by muse, mutect2, varscan2
- GPRASP1 | c.393A>G p.K131= | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as COSV64355502; called by muse, mutect2, varscan2
- HAPLN4 | c.630C>T p.N210= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs771835797, COSV52269416, COSV52270158; called by muse, mutect2, varscan2
- HDAC10 | c.1272T>C p.V424= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV50543944; called by muse, mutect2, varscan2
- HIVEP2 | c.4305G>A p.L1435= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs747221658, COSV50011486; called by muse, mutect2, varscan2
- IGHM | c.1152T>C p.P384= | Silent (SNP) | VAF 19/75 reads (25%) | called by muse, mutect2, varscan2
- KCNA1 | c.90C>T p.H30= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV66837224; called by muse, mutect2, varscan2
- KDM2A | c.474G>A p.Q158= | Silent (SNP) | VAF 37/87 reads (43%) | catalogued as COSV67081964; called by muse, mutect2, varscan2
- LRRC4C | c.588G>T p.L196= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV53424797; called by muse, mutect2, varscan2
- LRRC8E | c.1194C>G p.L398= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as COSV60717977; called by muse, mutect2, varscan2
- MAGEB6 | c.468G>A p.S156= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as rs777376582, COSV66871871, COSV66872222; called by muse, mutect2
- MAP2K7 | c.1098G>A p.R366= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs761282228, COSV67608171; called by muse, mutect2, varscan2
- MED12L | c.5109C>T p.Y1703= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as rs767901074, COSV56377792; called by muse, mutect2
- MED24 | c.1617C>T p.I539= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV62418513; called by muse, mutect2, varscan2
- NCK2 | c.135C>A p.A45= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV51891087, COSV51894398; called by muse, mutect2, varscan2
- NIPAL3 | c.246G>A p.L82= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV50231396; called by muse, mutect2, varscan2
- NOTCH3 | c.5460C>T p.I1820= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV54634156; called by muse, mutect2, varscan2
- PCDHA2 | c.1812C>T p.N604= | Silent (SNP) | VAF 35/195 reads (18%) | catalogued as rs1554120103, COSV65366812; called by muse, mutect2, varscan2
- PCDHA3 | c.1368G>A p.S456= | Silent (SNP) | VAF 74/232 reads (32%) | catalogued as COSV63541117; called by muse, mutect2, varscan2
- PEAK1 | c.4449G>A p.G1483= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV56934755; called by muse, mutect2, varscan2
- PHLDB3 | c.1008C>T p.F336= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV52669340; called by muse, mutect2, varscan2
- PHOX2B | c.282G>A p.E94= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV99891772; called by muse, mutect2, varscan2
- PLXNB2 | c.1452C>G p.P484= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV63781422; called by muse, mutect2, varscan2
- PLXNC1 | c.4059G>A p.K1353= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV51574732; called by muse, mutect2, varscan2
- PPP1R15A | c.897C>G p.L299= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs138608463; called by muse, mutect2, varscan2
- PPP1R9A | c.585T>C p.T195= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV56891588; called by muse, mutect2, varscan2
- PSKH2 | c.699T>G p.V233= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV52610329; called by muse, mutect2, varscan2
- RTEL1 | c.390C>G p.S130= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV58893573; called by muse, mutect2, varscan2
- RTN4 | c.1341C>T p.F447= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV58267409; called by muse, mutect2, varscan2
- SEMA5B | c.1836C>T p.F612= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as rs766999019, COSV52097012; called by muse, mutect2, varscan2
- SLC16A11 | c.702C>A p.L234= (on ENST00000308009; = p.L210= on NM_153357.3) | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as COSV57274198; called by muse, mutect2
- SLC6A6 | c.666C>G p.L222= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as rs1283307219, COSV100692189, COSV62649549; called by muse, mutect2, varscan2
- SLC6A7 | c.1266G>A p.K422= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV57938169; called by muse, mutect2, varscan2
- SLC7A3 | c.699C>T p.D233= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV53227359; called by muse, mutect2
- SOBP | c.1101G>A p.Q367= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV57998027; called by muse, mutect2, varscan2
- SPOCD1 | c.486C>G p.L162= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV57096085, COSV57097891; called by muse, mutect2, varscan2
- STUB1 | c.387G>A p.L129= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs757323165, COSV50197447; called by muse, mutect2, varscan2
- TCTN2 | c.594C>T p.F198= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs759913219, COSV57632779; ClinVar: likely benign; called by muse, mutect2, varscan2
- TEKT4 | c.1098G>A p.L366= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV54624684; called by muse, mutect2
- TMC2 | c.2061A>G p.K687= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as COSV62652426, COSV62656641; called by muse, mutect2, varscan2
- TNS2 | c.861C>T p.F287= (on ENST00000314250 / NM_170754.4; = p.F297= on NM_015319.2) | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs773909536, COSV58577149; called by muse, mutect2, varscan2
- TPSD1 | c.504C>T p.G168= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs201223052, COSV99273838; called by muse, mutect2, varscan2
- TTC30A | c.1083C>T p.F361= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV63101344; called by muse, mutect2, varscan2
- VSIG1 | c.396C>G p.L132= | Silent (SNP) | VAF 5/74 reads (7%) | catalogued as COSV99480513; called by muse, mutect2
- WDR37 | c.675C>T p.I225= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs770901554, COSV54128118; called by muse, mutect2, varscan2
- WDR4 | c.940C>T p.L314= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as rs780367869, COSV57733388; called by muse, mutect2, varscan2
- ZKSCAN8 | c.1047C>T p.P349= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV57638143; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73822774 C>A | 5'Flank (SNP) | VAF 11/70 reads (16%) | called by muse, mutect2, varscan2
- FAM184A | c.159+9078G>T | Intron (SNP) | VAF 13/43 reads (30%) | catalogued as rs1184343222, COSV58854120; called by muse, mutect2, varscan2
- MGAM | c.4618+3224G>A | Intron (SNP) | VAF 32/75 reads (43%) | catalogued as rs756584984, COSV72074562; called by muse, mutect2, varscan2
- MUC2 | chr11:1099769 C>T | 5'Flank (SNP) | VAF 21/57 reads (37%) | catalogued as rs756605304; called by muse, mutect2, varscan2
- OR2U1P | n.738C>A | RNA (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- RNU7-174P | chr8:80559577 T>A | 5'Flank (SNP) | VAF 13/20 reads (65%) | called by muse, mutect2, varscan2
- SNORD114-1 | n.16G>C | RNA (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- ZNF833P | n.662C>G | RNA (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2, varscan2
